Somatic mutation profile of tumor specimen HTMCP-03-06-02321-01A (aliquot HTMCP-03-06-02321-01A-01D-9006) from CGCI case HTMCP-03-06-02321, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02321-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00c4c324-19ce-489c-bccd-fdfdd0a1a6da.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02321-10A (Blood Derived Normal), aliquot HTMCP-03-06-02321-10A-01D-9006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9d5bff5-1882-465e-b120-4d0b35209c3a

The open-access MAF lists 39 somatic variants for this specimen: 27 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 11, Nonsense Mutation 4, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY2 | c.1904C>A p.A635E | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV57868296; called by muse, mutect2, varscan2
- ALK | c.2269G>A p.V757M | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs371005946; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSF2RA | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs762479130, COSV62626873; called by muse, mutect2
- DNHD1 | c.13594C>T p.R4532C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs1453485435, COSV54432610; called by muse, mutect2, varscan2
- EPHA2 | c.1619G>T p.G540V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.522); catalogued as COSV100626342; called by muse, mutect2, varscan2
- HIVEP1 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1451041533, COSV65105757; called by muse, mutect2, varscan2
- LAMA2 | c.8222C>T p.T2741M | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as rs766816598, COSV70348122; called by muse, mutect2, varscan2
- MAD1L1 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs77541266, COSV56228204; called by mutect2, varscan2
- NBEA | c.7210G>A p.D2404N | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV59810443, COSV59831493; called by muse, mutect2
- NDRG1 | c.12G>T p.E4D | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1286565668; called by muse, mutect2, varscan2
- NSD1 | c.905C>G p.S302C | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.525); catalogued as rs1159878880, COSV61778636; called by muse, mutect2, varscan2
- NSD1 | c.5782G>T p.G1928* | Nonsense Mutation (SNP) | VAF 36/91 reads (40%) | catalogued as COSV100729616, COSV61785493; called by muse, mutect2, varscan2
- OCRL | c.2549C>G p.S850C | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63981259; called by muse, mutect2, varscan2
- PATJ | c.4424G>C p.R1475T | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs1334641070; called by muse, varscan2
- ROBO3 | c.862C>A p.R288S | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV67302670; called by muse, mutect2, varscan2
- SF1 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57111668; called by muse, mutect2, varscan2
- WBP1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs534766337, COSV51971528; called by muse, mutect2, varscan2
- CFH | c.809C>A p.P270H | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DST | c.5477C>G p.S1826* | Nonsense Mutation (SNP) | VAF 38/159 reads (24%) | called by muse, mutect2, varscan2
- KCNT2 | c.1891C>G p.P631A | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRP1 | c.11030A>G p.D3677G | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- MCRS1 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- OCRL | c.2441C>G p.S814C | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPWD1 | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 45/210 reads (21%) | called by muse, mutect2, varscan2
- SMG1 | c.1553C>G p.S518* | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- TAF5L | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- TNN | c.1260G>T p.K420N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- BTAF1 | c.3249G>T p.V1083= | Silent (SNP) | VAF 30/152 reads (20%) | called by muse, mutect2, varscan2
- EPHA2 | c.1620C>T p.G540= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs764283263, COSV64454732; called by muse, mutect2, varscan2
- KIAA1217 | c.5217C>T p.S1739= | Silent (SNP) | VAF 25/93 reads (27%) | called by muse, mutect2, varscan2
- MROH2B | c.834C>T p.I278= | Silent (SNP) | VAF 33/107 reads (31%) | called by muse, mutect2, varscan2
- NDOR1 | c.1698G>A p.A566= (on ENST00000371521 / NM_001144026.3; = p.A550= on NM_014434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs372825957, COSV100788823; called by muse, mutect2, varscan2
- PHF8 | c.1209C>A p.I403= (on ENST00000357988 / NM_001184896.1; = p.I367= on NM_015107.3) | Silent (SNP) | VAF 32/186 reads (17%) | called by muse, mutect2, varscan2
- PTPRT | c.3738C>T p.F1246= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as rs750078390, COSV61967976; called by muse, mutect2, varscan2
- SMARCA4 | c.1221C>T p.L407= | Silent (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- SMARCA4 | c.1302C>G p.L434= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2
- UBE2O | c.678C>T p.N226= | Silent (SNP) | VAF 26/131 reads (20%) | catalogued as rs568559821; called by muse, mutect2, varscan2
- ZMYND8 | c.2904G>A p.E968= (on ENST00000311275 / NM_001363741.2; = p.E942= on NM_012408.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV53696825; called by muse, mutect2, varscan2
- CNGA3 | c.-7C>T | 5'UTR (SNP) | VAF 51/248 reads (21%) | catalogued as rs763400398, COSV55627562; called by muse, mutect2, varscan2
